Somatic mutation profile of tumor specimen TCGA-X7-A8DD-01A (aliquot TCGA-X7-A8DD-01A-11D-A423-09) from TCGA case TCGA-X7-A8DD, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B1, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 54.7 years (19,971 days).
Specimen TCGA-X7-A8DD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22bbd43c-ac31-4c8c-8abe-d16a4b25fe11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8DD-10A (Blood Derived Normal), aliquot TCGA-X7-A8DD-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fe0786d-258f-49c6-970e-09a3d57a0fd8

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, Splice Site 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 16/442 reads (4%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2
- PCDHA9 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs782301409, COSV65323477; called by muse, mutect2, varscan2
- PTPRD | c.5693G>A p.R1898H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as rs200610422, COSV61956932; called by mutect2, varscan2
- MTERF3 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 4/94 reads (4%) | called by muse, mutect2
- RAB3GAP2 | c.170C>A p.P57Q | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- S100PBP | c.1112+1G>A p.X371_splice | Splice Site (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2
- SLC38A7 | c.1331G>A p.G444E | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTERF3 | c.873G>C p.L291= | Silent (SNP) | VAF 4/91 reads (4%) | called by muse, mutect2
